Somatic mutation profile of tumor specimen TARGET-10-PAREIV-09A (aliquot TARGET-10-PAREIV-09A-01D) from TARGET case TARGET-10-PAREIV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,107 days).
Specimen TARGET-10-PAREIV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6704ef02-7f81-4c75-bd0c-7595e977c77b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAREIV-10A (Blood Derived Normal), aliquot TARGET-10-PAREIV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e7ad633-a5fa-4a01-b368-85195f996699

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Frame Shift Ins 1, 3'UTR 1, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HNF1A | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as rs754729248, CD064653, CM082829, CM082830, CM082831; called by muse, mutect2, varscan2
- TBL1XR1 | c.419_420insGG p.I141Vfs*2 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | catalogued as COSV61789638, COSV61790464; called by mutect2, pindel, varscan2
- OR6C6 | c.284G>A p.C95Y | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- HYDIN | c.9972T>C p.C3324= | Silent (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2, varscan2
- DLG2 | c.205-65878G>T | Intron (SNP) | VAF 13/36 reads (36%) | catalogued as COSV99716695; called by muse, mutect2, varscan2
- PTPRZ1 | c.*28C>A | 3'UTR (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
